Surgical pathology report (de-identified scan), TCGA case TCGA-AF-6672, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-AF-6672-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Date Coll: [REDACTED]

SURGICAL PATHOLOGY REPORT

SPECIMEN

- A. Colon for rule out metastatic colon cancer
- B. Rectosigmoid colon

CLINICAL NOTES

--

FROZEN SECTION DIAGNOSIS

- A - Adipose tissue with metastatic adenocarcinoma. [REDACTED]

GROSS DESCRIPTION

A. The specimen is received fresh for frozen section labeled "metastatic colon cancer". It consists of a portion of adipose tissue measuring 2.2 x 1.6 x 1 cm. In the center there is a poorly demarcated firm dull tan nodule measuring 0.5 cm. in diameter. A touch preparation is made and a sample is taken for frozen section. The remainder of the tissue is submitted in one block following fixation.

B. Received fresh, subsequently fixed in formalin, labeled "rectosigmoid colon" is a specimen that consists of a 25 cm long portion of colon. The specimen is inked blue at the proximal end and at the distal end it is inked black. The serosa is pink-tan, smooth, glistening and predominantly fatty. There is a serosal umbilication 8.0 cm. from the distal end. The specimen shows retroperitoneal reflection which is 7 cm from the distal margin. The specimen is opened to show a pink-tan smooth glistening mucosa with a 3.5 cm circumference at the proximal end and an 8 cm circumference at the distal end. There is a nearly circumferential tumor which is 6.5 x 4.5 x 0.8 cm. On sectioning, the specimen showed invasion through the muscularis propria and into the fat. This is somewhat contiguous with the umbilication grossly identified on the serosa of the specimen. This area is inked blue. Tumor comes within 6.5 cm of the distal margin. It grossly spares the radial margin. The fatty tissue is sectioned to show multiple lymph nodes grossly identified which range from 0.8 cm to 2.5 cm in greatest dimension. No other discrete gross lesions are identified. Representative sections of the specimen are submitted as follows: Block 1 - representative luminal margins; blocks 2-5 - representative sections of tumor which include tumor to deep and fat, tumor to normal and tumor to serosal umbilication; blocks 6-13 - whole lymph nodes; block 14 - has one possible lymph node bisected; block [REDACTED] - representative section of possibly matted lymph nodes. RS-15. [REDACTED]

REPORT REVISED ON [REDACTED]

[REDACTED]

[page 2 of 2]
[REDACTED]

MICROSCOPIC DESCRIPTION

A. Microscopic examination performed.

B. A deeply invasive, moderately differentiated adenocarcinoma is present in the rectosigmoid. Please see the template below.

Histologic type: Invasive adenocarcinoma

Histologic grade: Moderately differentiated

Primary tumor (pT): Tumor penetrates the visceral peritoneum, pT4a

Proximal margin: Negative

Distal margin: Negative

Circumferential (radial) margin: Negative

Distance of tumor from closest margin: Tumor is present to within 6.5 cm. of the distal margin

Vascular invasion: Not found

Regional lymph nodes (pN): 37 regional lymph nodes are found, 18 of which contain metastatic adenocarcinoma, 18/37, pN2b

Non-lymph node pericolic tumor: Numerous foci of soft tissue metastases present.

Distant metastasis (pM): Cannot be assessed.
64,3, 5

REPORT REVISED ON [REDACTED]

AT [REDACTED]

DIAGNOSIS

A. Rule out metastatic colon cancer, excision -

Adipose tissue with metastatic moderately differentiated adenocarcinoma, compatible with colonic origin.
No lymphatic invasion is found.

B. Rectosigmoid colon, segmental resection -

Rectosigmoid colon with moderately differentiated adenocarcinoma extending into pericolic fat, penetrating the visceral peritoneum. Numerous pericolic soft tissue metastases present
7 lymph nodes.

[REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file 0ce8591e-f4bf-49b8-95a2-4983816c80b1 (TCGA-AF-6672.456C7370-D463-4BA7-87D2-55549A0DD2A4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).